CPTAC case C243909 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/99630205-1e2b-4d0b-a3d3-a6cb21b64046

Demographics
Sex at birth: female; Age at index: 59 years; Vital status: Dead; Days to death: 330 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Cerebrum; Last known disease status: With tumor; Days to last known disease status: 330 days; Progression or recurrence: yes; Days to recurrence: 217 days; Sites of involvement: Brain, Cerebrum; Tumor focality: Unifocal.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified; Pack years smoked: 20; Cigarettes per day: 10; Alcohol history: Yes.

Biospecimens (7 samples)
- Samples 1104772, 1104778, 1105235, 1105241, SM-JU342, SM-JU34E (6 with the same recorded description): Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Biospecimen laterality: Left; Preservation method: Snap Frozen.
- Sample 1105279: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
